CCDI case PBCPNH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/e5402223-869f-47cf-8784-0a45292f9431

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Granulosa cell tumor, juvenile: ICD-O-3 morphology code: 8622/1; Tissue or organ of origin: Ovary; Age at diagnosis: 16.4 years (6,008 days).

Biospecimens (3 samples)
- Sample 0DWWMF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWWMM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWWMV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
